Somatic mutation profile of tumor specimen 0DE3HJ from CCDI case PBBPKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.9 years (6,180 days).
Specimen 0DE3HJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e7df8ed-1ee3-47d5-b0a3-c329703a792e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE3GS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1c40186-9e8f-44a4-8ae1-007d565ba9aa

The open-access MAF lists 77 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Intron 7, Nonsense Mutation 4, 5'UTR 4, 3'UTR 4, Frame Shift Del 2, RNA 2, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, varscan2
- ANKRD13C | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs544286608; called by muse, mutect2, varscan2
- BDNF | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 50/332 reads (15%) | catalogued as rs772989712, COSV59234017; called by muse, varscan2
- CCDC88C | c.4496G>A p.R1499H | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs752609625; called by muse, mutect2, varscan2
- DDX3X | c.1168-2A>G p.X390_splice (on ENST00000399959; = p.X391_splice on NM_001356.5) | Splice Site (SNP) | VAF 102/104 reads (98%) | catalogued as COSV67863867; called by muse, mutect2, varscan2
- KMT2D | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 128/287 reads (45%) | catalogued as COSV99987566; called by muse, mutect2, varscan2
- MYH14 | c.5656C>T p.R1886W | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772329850; called by muse, varscan2
- NET1 | c.1490G>A p.R497Q (on ENST00000355029 / NM_001047160.3; = p.R443Q on NM_005863.5) | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs149676418; called by muse, mutect2, varscan2
- NHLH2 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57202346; called by muse, mutect2, varscan2
- NUMBL | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99424887; called by muse, mutect2
- OR1S1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 24/626 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as rs1371556276, COSV58706382; called by muse, mutect2
- OR1S2 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 36/604 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs200054918, COSV56918693; called by muse, mutect2
- OR2M5 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 87/445 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV63545668; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- SLTM | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99989360; called by muse, varscan2
- TEX13D | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs1364180197, COSV69794684; called by muse, mutect2, varscan2
- TEX13D | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV69794686; called by muse, mutect2, varscan2
- ZBED5 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs780011941; called by muse, varscan2
- ACSS3 | c.1782A>T p.K594N | Missense Mutation (SNP) | VAF 111/417 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ASXL3 | c.4051C>T p.P1351S | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 44/527 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 31/239 reads (13%) | called by muse, varscan2
- CD163L1 | c.1052G>C p.C351S | Missense Mutation (SNP) | VAF 31/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CD180 | c.680T>C p.L227S | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CEACAM3 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 20/511 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- CHD7 | c.5259A>G p.I1753M | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, varscan2
- CSNK1A1 | c.83T>G p.F28C | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD5 | c.3907_3910dup p.G1304Afs*38 | Frame Shift Ins (INS) | VAF 95/292 reads (33%) | called by mutect2, varscan2
- GPLD1 | c.1352G>C p.G451A | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KMT2C | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MUC16 | c.29848G>T p.E9950* | Nonsense Mutation (SNP) | VAF 99/291 reads (34%) | called by muse, mutect2, varscan2
- NDST3 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NEURL1 | c.776_809del p.G259Afs*234 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | called by mutect2, varscan2
- NRAP | c.1843G>C p.V615L (on ENST00000359988 / NM_001322945.2; = p.V580L on NM_006175.4) | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.115); called by muse, varscan2
- NSUN3 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDZRN4 | c.1153A>T p.I385F (on ENST00000402685 / NM_001164595.2; = p.I127F on NM_013377.4) | Missense Mutation (SNP) | VAF 155/606 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKDC | c.9916_9917del p.L3306Vfs*3 | Frame Shift Del (DEL) | VAF 110/230 reads (48%) | called by mutect2, varscan2
- RDM1 | c.654G>T p.L218F | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); called by muse, varscan2
- SORCS1 | c.2762T>G p.L921R | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- SPAG17 | c.4776G>C p.Q1592H | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- ST6GALNAC1 | c.1416-2A>G p.X472_splice | Splice Site (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- TEP1 | c.467G>C p.S156T | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- USP17L10 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 23/449 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADGRB3 | c.1797C>A p.T599= | Silent (SNP) | VAF 111/299 reads (37%) | called by muse, mutect2, varscan2
- AFF3 | c.2145G>A p.G715= | Silent (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- ANKRD33 | c.810G>A p.G270= | Silent (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- CHD6 | c.1500T>C p.L500= | Silent (SNP) | VAF 20/542 reads (4%) | called by muse, mutect2
- FAM193A | c.3411C>T p.S1137= | Silent (SNP) | VAF 67/426 reads (16%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.378C>T p.L126= | Silent (SNP) | VAF 70/196 reads (36%) | catalogued as rs760274970; called by muse, mutect2, varscan2
- KMT2D | c.1182G>T p.G394= | Silent (SNP) | VAF 118/262 reads (45%) | called by mutect2, varscan2
- MBD2 | c.168C>T p.G56= | Silent (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- PSMB5 | c.261C>T p.S87= | Silent (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- RADIL | c.714C>T p.P238= | Silent (SNP) | VAF 80/198 reads (40%) | catalogued as rs373368530; called by muse, mutect2, varscan2
- SMARCAD1 | c.3012A>T p.V1004= | Silent (SNP) | VAF 34/238 reads (14%) | catalogued as rs1038161057; called by muse, mutect2, varscan2
- TSHZ3 | c.525G>A p.T175= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs368807538; called by muse, mutect2, varscan2
- VSIG4 | c.123C>T p.C41= | Silent (SNP) | VAF 109/112 reads (97%) | called by muse, mutect2, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, varscan2
- ANKRD28 | c.2784-37G>A | Intron (SNP) | VAF 12/94 reads (13%) | called by muse, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 31/410 reads (8%) | called by muse, mutect2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- COPS2 | c.715+50T>A | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- COX11 | chr17:54968693 A>G | 5'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- CYP21A2 | c.292+38T>A | Intron (SNP) | VAF 10/98 reads (10%) | catalogued as rs1288475272; called by muse, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- GPSM2 | c.-33A>T | 5'UTR (SNP) | VAF 9/119 reads (8%) | called by mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 12/93 reads (13%) | catalogued as rs768118261; called by mutect2, varscan2
- OTOF | c.-22G>C | 5'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- RABAC1 | c.*95G>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | catalogued as rs1423799657; called by muse, mutect2, varscan2
- RANGAP1 | c.-38-22A>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- REV3L | c.7419+59T>A | Intron (SNP) | VAF 14/128 reads (11%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 15/132 reads (11%) | called by muse, varscan2
- SLCO2A1 | chr3:133928868 A>G | 3'Flank (SNP) | VAF 6/35 reads (17%) | called by muse, varscan2
- ZNF224 | c.142+99A>T | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, varscan2
- ZNF501 | c.-5G>A | 5'UTR (SNP) | VAF 222/330 reads (67%) | catalogued as COSV101247049, COSV101247143; called by muse, mutect2, varscan2
